Somatic mutation profile of tumor specimen TCGA-04-1346-01A (aliquot TCGA-04-1346-01A-01W-0488-09) from TCGA case TCGA-04-1346, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 73.6 years (26,865 days).
Specimen TCGA-04-1346-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d3fd7a3-8aec-4d45-ad90-15cd680210f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1346-11A (Solid Tissue Normal), aliquot TCGA-04-1346-11A-01W-0487-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76b319c6-d768-41fe-b86f-d487ee81c9bd

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 12, Frame Shift Del 2, In Frame Del 1, 5'UTR 1, Splice Site 1, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANLN | c.2804G>A p.R935Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462474727, COSV56074462; called by muse, mutect2, varscan2
- CARMIL1 | c.3782C>T p.S1261F | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.309); catalogued as COSV61519950; called by muse, mutect2
- CDH7 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59887000; called by muse, mutect2
- COL6A1 | c.2347C>G p.R783G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV62611795, COSV62614078, COSV62614097; called by muse, mutect2, varscan2
- CRTAM | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV57069177; called by muse, mutect2, varscan2
- DLC1 | c.1174-1G>A p.X392_splice | Splice Site (SNP) | VAF 48/153 reads (31%) | catalogued as COSV52312634; called by muse, mutect2, varscan2
- FAM20A | c.455dup p.L153Tfs*17 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | catalogued as rs746662580; called by pindel, varscan2
- FERMT1 | c.1945G>A p.G649S | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs558908354, COSV54094657; called by muse, mutect2, varscan2
- GPR158 | c.3322C>T p.R1108C | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs372238950, COSV66267514; called by muse, mutect2
- GRID2 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56169233; called by muse, mutect2, varscan2
- HAL | c.1801G>C p.E601Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as rs377498665, COSV54118686; called by muse, varscan2
- HECTD4 | c.5596G>A p.V1866M | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1462456626, COSV66388755; called by muse, mutect2
- HMGCR | c.829C>G p.P277A | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV55316544; called by muse, mutect2, varscan2
- IFT52 | c.1266G>T p.Q422H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.807); catalogued as COSV65975439; called by muse, mutect2, varscan2
- ITIH3 | c.968T>C p.I323T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV69649420; called by muse, mutect2
- LAMA2 | c.7585G>A p.V2529I | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV70351045; called by muse, mutect2, varscan2
- LTN1 | c.5224C>A p.H1742N | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63734291; called by muse, mutect2, varscan2
- MAST1 | c.1245G>C p.Q415H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52249665; called by muse, mutect2, varscan2
- MED12L | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 77/550 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV56385268; called by muse, varscan2
- MTERF4 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV99613033; called by muse, mutect2
- OR51G1 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV58969732; called by muse, mutect2, varscan2
- PPBP | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as COSV56019987; called by muse, mutect2, varscan2
- QSER1 | c.5143T>C p.W1715R (on ENST00000399302; = p.W1844R on NM_001076786.3) | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67901094; called by muse, mutect2, varscan2
- RMC1 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.735); catalogued as rs771005240, COSV52572227; called by muse, mutect2, varscan2
- SNRNP200 | c.3638A>G p.K1213R | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV60491679; called by muse, mutect2, varscan2
- SPECC1 | c.934T>C p.S312P | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV54961221; called by muse, mutect2, varscan2
- TAF1B | c.1602T>A p.N534K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.622); catalogued as COSV55157572; called by muse, mutect2, varscan2
- UNC45B | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52098294; called by muse, mutect2, varscan2
- ITGB1BP1 | c.321_323del p.E109del | In Frame Del (DEL) | VAF 16/86 reads (19%) | called by pindel, varscan2
- TRIM2 | c.1994del p.G665Efs*11 (on ENST00000437508; = p.G692Efs*11 on NM_015271.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 55/129 reads (43%) | called by mutect2, pindel, varscan2
- USF3 | c.2638_2639del p.V880Ifs*4 | Frame Shift Del (DEL) | VAF 41/318 reads (13%) | called by mutect2, pindel, varscan2
- FSHB | c.261T>C p.H87= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV54222375; called by muse, mutect2, varscan2
- KCNAB3 | c.780G>A p.L260= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs1179543842, COSV58140835; called by muse, mutect2, varscan2
- L3MBTL3 | c.651G>A p.S217= | Silent (SNP) | VAF 57/392 reads (15%) | catalogued as rs1235743643, COSV62387065; called by muse, mutect2, varscan2
- LPCAT1 | c.801C>T p.N267= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV52039202; called by muse, mutect2, varscan2
- LRRIQ1 | c.3729T>C p.T1243= | Silent (SNP) | VAF 39/71 reads (55%) | catalogued as rs1478065393, COSV67833525; called by muse, mutect2, varscan2
- PLEKHG6 | c.1264C>A p.R422= | Silent (SNP) | VAF 2/20 reads (10%) | called by muse, mutect2
- PTPRT | c.3723G>A p.K1241= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV61994856; called by muse, mutect2, varscan2
- TMEM159 | c.465C>T p.F155= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as rs939874083, COSV51785528; called by muse, mutect2, varscan2
- TRDC | c.219A>C p.S73= | Silent (SNP) | VAF 34/144 reads (24%) | called by muse, varscan2
- TSHZ3 | c.621C>T p.I207= | Silent (SNP) | VAF 57/402 reads (14%) | catalogued as COSV53675470; called by muse, mutect2, varscan2
- UBA6 | c.1485T>C p.V495= | Silent (SNP) | VAF 13/205 reads (6%) | catalogued as COSV100451999; called by muse, mutect2
- YIPF3 | c.813C>T p.P271= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100397185; called by muse, mutect2
- MIR20B | n.44A>G | RNA (SNP) | VAF 135/266 reads (51%) | called by muse, mutect2, varscan2
- SLC6A1 | c.-1C>T | 5'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99823331; called by muse, mutect2, varscan2
- ZNF493 | c.-132+7891A>G | Intron (SNP) | VAF 67/417 reads (16%) | catalogued as COSV60550549; called by muse, varscan2
